Somatic mutation profile of tumor specimen MMRF_2132_1_BM_CD138pos (aliquot MMRF_2132_1_BM_CD138pos_T1_KHS5U_L08764) from MMRF case MMRF_2132, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 87.6 years (32,005 days).
Specimen MMRF_2132_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59ec1c50-6db0-48ff-a79f-d5f27abf85fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2132_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2132_1_PB_Whole_C2_KHS5U_L08768; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2925af97-9f9c-4b09-82c8-a038048f43b4

The open-access MAF lists 118 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 32, Silent 15, Intron 12, Frame Shift Del 5, 5'Flank 4, RNA 4, Nonsense Mutation 2, In Frame Del 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKBKB | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1563340753, COSV60596575; ClinVar: pathogenic; called by muse, mutect2
- DROSHA | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60776796; called by muse, mutect2, varscan2
- EIF2AK3 | c.1267A>G p.I423V | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1193307627; called by muse, mutect2, varscan2
- FAT2 | c.6919G>A p.V2307I | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as rs753725973; called by muse, mutect2, varscan2
- IGHV3-33 | c.139A>C p.T47P | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs778875444; called by muse, varscan2
- MAFA | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61087744; called by muse, mutect2, varscan2
- MYH13 | c.3149C>T p.A1050V | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1478875991; called by muse, mutect2, varscan2
- OR4B1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58882172, COSV58882854; called by muse, mutect2, varscan2
- POT1 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296966928, COSV100714174, COSV104423892; called by muse, mutect2, varscan2
- SLC27A1 | c.1682G>A p.S561N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53100342; called by muse, mutect2, varscan2
- SLCO1B1 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57009440; called by muse, mutect2, varscan2
- SLCO3A1 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs201801796; called by muse, mutect2, varscan2
- ADAM22 | c.2063G>A p.C688Y | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2
- ALKBH5 | c.659del p.F220Sfs*34 | Frame Shift Del (DEL) | VAF 103/448 reads (23%) | called by mutect2, pindel, varscan2
- AMT | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BHLHE41 | c.561C>G p.S187R | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- BNC2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- BTBD16 | c.1245_1246del p.Y416* | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- C14orf39 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD101 | c.2245del p.Q749Kfs*18 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | called by mutect2, pindel
- DKK4 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DLG5 | c.4348C>T p.H1450Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- DROSHA | c.2513T>C p.V838A | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- FAM186A | c.1601G>A p.G534D | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRG2 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- H1-4 | c.133A>C p.T45P | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- HCN1 | c.1999G>C p.V667L | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HM13 | c.413A>C p.Y138S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- IZUMO1R | c.667G>T p.A223S (on ENST00000440961; = p.A230S on NM_001199206.3) | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.19); called by muse, mutect2
- KCNH5 | c.2588C>A p.S863Y | Missense Mutation (SNP) | VAF 128/310 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KRT23 | c.786G>T p.W262C | Missense Mutation (SNP) | VAF 27/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LDLRAD3 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 120/275 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- MAN2A1 | c.2960del p.R987Kfs*22 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- MASTL | c.2401G>A p.E801K (on ENST00000375940 / NM_001372029.1; = p.E800K on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL58 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MS4A13 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.888); called by muse, mutect2
- MUC16 | c.36700C>G p.L12234V | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.224); called by muse, mutect2
- NFKBIA | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- PHLPP1 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RASL12 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- RNASEH2B | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 56/165 reads (34%) | called by muse, mutect2, varscan2
- RNF43 | c.1468del p.V490Sfs*12 | Frame Shift Del (DEL) | VAF 22/160 reads (14%) | called by mutect2, pindel, varscan2
- RPS6KC1 | c.875_877del p.R292del | In Frame Del (DEL) | VAF 114/249 reads (46%) | called by pindel, varscan2
- TFDP3 | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 49/63 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TMCC2 | c.978G>C p.K326N | Missense Mutation (SNP) | VAF 138/252 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TRAF3 | c.1031G>A p.W344* | Nonsense Mutation (SNP) | VAF 65/67 reads (97%) | called by muse, mutect2, varscan2
- VPS13D | c.5102C>A p.A1701E | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.034); called by muse, mutect2
- WWC2 | c.111C>G p.S37R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF618 | c.2695A>T p.K899* (on ENST00000374126 / NM_001318042.2; = p.K806* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- ADAMTS10 | c.2793G>A p.P931= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV54353043; called by muse, mutect2, varscan2
- ARHGEF1 | c.2370C>T p.N790= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as rs376174015; called by muse, mutect2, varscan2
- GPR149 | c.369G>T p.A123= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV67666995; called by muse, mutect2, varscan2
- HOXD10 | c.165G>A p.P55= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs1438215691, COSV50898406; called by muse, mutect2, varscan2
- IGHV3-33 | c.150C>T p.S50= | Silent (SNP) | VAF 62/128 reads (48%) | catalogued as rs372905804; called by muse, varscan2
- IRX2 | c.1029G>A p.P343= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- LTBP4 | c.4761G>C p.L1587= (on ENST00000308370 / NM_001042544.1; = p.L1550= on NM_003573.2) | Silent (SNP) | VAF 79/335 reads (24%) | called by muse, mutect2, varscan2
- NCKAP5 | c.5172C>G p.T1724= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as COSV58469765; called by muse, mutect2, varscan2
- SMOC2 | c.729C>T p.G243= (on ENST00000356284 / NM_001166412.2; = p.G254= on NM_022138.3) | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs200774380; called by muse, mutect2, varscan2
- TAS2R42 | c.762T>C p.N254= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs530163269; called by muse, mutect2, varscan2
- TEX45 | c.1461G>A p.E487= | Silent (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- TMEM42 | c.147C>T p.F49= | Silent (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- TNFRSF21 | c.450T>C p.C150= | Silent (SNP) | VAF 14/326 reads (4%) | catalogued as rs1018010608; called by muse, mutect2
- XPR1 | c.2007G>C p.L669= | Silent (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- ZP4 | c.1605A>T p.P535= | Silent (SNP) | VAF 103/559 reads (18%) | called by muse, mutect2, varscan2
- ACVR2A | c.1217-104C>T | Intron (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- AGO2 | c.*379G>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- AL356585.2 | n.2092C>A | RNA (SNP) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- ALDH8A1 | c.*59A>G | 3'UTR (SNP) | VAF 34/214 reads (16%) | catalogued as rs919134614; called by muse, mutect2
- AMZ1 | c.*1314G>C | 3'UTR (SNP) | VAF 36/74 reads (49%) | catalogued as rs996470964; called by muse, mutect2, varscan2
- ARHGAP27 | c.1248+14dup | Intron (INS) | VAF 18/160 reads (11%) | called by mutect2, pindel
- BCL7A | chr12:122020986 del CCGCTGCAG | 5'Flank (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- BTN2A3P | n.1588C>T | RNA (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- CALHM5 | c.*8509C>T | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- CD300LB | c.*51C>T | 3'UTR (SNP) | VAF 74/216 reads (34%) | catalogued as rs372723877, COSV58726531; called by muse, mutect2, varscan2
- CFD | c.*170T>C | 3'UTR (SNP) | VAF 5/86 reads (6%) | catalogued as rs893194845; called by muse, mutect2
- CHI3L1 | c.*61G>T | 3'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- CRYAB | c.325-286T>C | Intron (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- DCDC2 | c.*1199T>G | 3'UTR (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- DIAPH3 | c.*303del | 3'UTR (DEL) | VAF 9/119 reads (8%) | called by mutect2, pindel*
- EFCAB13 | c.2638+159A>G | Intron (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- F7 | c.*289G>A | 3'UTR (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- FIGN | c.*2002A>T | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- GNAQ | c.*1550C>G | 3'UTR (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- GRIK3 | c.*3230G>A | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- HMGA2 | c.*2670G>A | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- HRH1 | c.*878C>T | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- IDH3G | c.1080+103G>A | Intron (SNP) | VAF 52/53 reads (98%) | called by muse, mutect2, varscan2
- KCNT1 | chr9:135792430 C>T | 3'Flank (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- LINC02693 | n.3297G>A | RNA (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- LNPK | c.*5475_*5476insTA | 3'UTR (INS) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- MIR5195 | chr14:106851126 T>G | 5'Flank (SNP) | VAF 84/194 reads (43%) | catalogued as rs569234583; called by muse, mutect2, varscan2
- MYH16 | n.4254T>C | RNA (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- NCAM2 | c.*2608G>T | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- NTRK3 | c.*10811C>A | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- NUBP1 | c.820+21G>A | Intron (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- NUDT12 | c.*783G>A | 3'UTR (SNP) | VAF 8/140 reads (6%) | catalogued as rs1170720255; called by muse, mutect2
- NUP58 | c.1435+2180A>G | Intron (SNP) | VAF 6/83 reads (7%) | catalogued as rs903374609; called by muse, mutect2
- PAK5 | c.*180C>T | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- PGLYRP4 | c.*221G>T | 3'UTR (SNP) | VAF 45/85 reads (53%) | called by muse, mutect2, varscan2
- PLK2 | c.626-105G>A | Intron (SNP) | VAF 37/239 reads (15%) | catalogued as rs1427088945; called by muse, mutect2, varscan2
- PRR14L | c.*3395C>T | 3'UTR (SNP) | VAF 30/114 reads (26%) | catalogued as rs954191254; called by muse, mutect2, varscan2
- RASGEF1C | c.*118C>T | 3'UTR (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- RGPD1 | chr2:86903972 C>T | 5'Flank (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- RNPS1 | chr16:2271695 C>T | 5'Flank (SNP) | VAF 62/136 reads (46%) | catalogued as rs927266907; called by muse, mutect2, varscan2
- RPL14 | c.*2354G>A | 3'UTR (SNP) | VAF 76/154 reads (49%) | catalogued as rs1339921743; called by muse, mutect2, varscan2
- SCN9A | c.*372A>C | 3'UTR (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- SCNN1D | c.*210G>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- SESN3 | c.*1396G>C | 3'UTR (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- SHFL | c.22-58G>C | Intron (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- SLC23A3 | c.418+17G>A | Intron (SNP) | VAF 13/39 reads (33%) | catalogued as rs750950379; called by muse, mutect2, varscan2
- SOX9 | c.-135G>A | 5'UTR (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- SV2B | c.*4463G>A | 3'UTR (SNP) | VAF 13/226 reads (6%) | catalogued as rs1280053954; called by muse, mutect2
- TLL1 | c.*2174C>T | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- TMEM260 | c.*820C>G | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- TMOD3 | c.*2485A>G | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- TMTC1 | c.1532+3160A>G | Intron (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- TRIM9 | c.1604-818G>T | Intron (SNP) | VAF 69/151 reads (46%) | called by muse, mutect2, varscan2
- ZNF395 | c.*2245G>A | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
